Somatic mutation profile of tumor specimen TCGA-F4-6459-01A (aliquot TCGA-F4-6459-01A-11D-1771-10) from TCGA case TCGA-F4-6459, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 61.8 years (22,574 days).
Specimen TCGA-F4-6459-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 476385a3-c2a6-4d66-b29b-a4ee198ccbe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6459-10A (Blood Derived Normal), aliquot TCGA-F4-6459-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e318b394-206c-4576-9aad-65bea16de438

The open-access MAF lists 137 somatic variants for this specimen: 105 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 30, Nonsense Mutation 6, Frame Shift Del 6, Frame Shift Ins 4, Splice Site 3, RNA 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 60/107 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.61); catalogued as COSV99288117; called by muse, mutect2, varscan2
- ABCG8 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs766212636, CM012312, COSV55390446, COSV55393699; ClinVar: uncertain significance; called by mutect2, varscan2
- AC008397.2 | c.564C>A p.N188K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53207885; called by muse, mutect2, varscan2
- ACAP1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.537); catalogued as rs767071679, COSV50138819; called by muse, mutect2, varscan2
- ANKRD11 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 52/606 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs149939914, COSV99968627; called by muse, mutect2
- APC | c.3746del p.C1249Sfs*16 | Frame Shift Del (DEL) | VAF 65/137 reads (47%) | catalogued as CX1111622; called by mutect2, pindel, varscan2
- APLP1 | c.1328A>G p.Q443R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99697576; called by muse, mutect2
- APOL5 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.916); catalogued as rs369158723; called by muse, mutect2, varscan2
- ASAP1 | c.2073G>C p.Q691H | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV63044093; called by muse, mutect2, varscan2
- AXL | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV56563508; called by muse, mutect2, varscan2
- BTN2A2 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100760566, COSV61856531; called by muse, mutect2, varscan2
- C2orf16 | c.5324G>A p.R1775H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs540398491, COSV62673627; called by muse, mutect2, varscan2
- CCDC141 | c.1964A>G p.N655S | Missense Mutation (SNP) | VAF 149/623 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV55368346; called by muse, mutect2, varscan2
- CERS3 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs904261909, COSV52564617; called by muse, mutect2, varscan2
- CFAP251 | c.3394G>A p.A1132T | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as rs946309653, COSV56607473; called by muse, mutect2, varscan2
- CHST15 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as rs200319997, COSV60559964; called by muse, mutect2, varscan2
- CMA1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as rs755977857, COSV51625626; called by muse, mutect2, varscan2
- CNTN4 | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 74/196 reads (38%) | catalogued as rs1399339293, COSV100638994; called by muse, mutect2, varscan2
- CNTNAP3 | c.3316G>T p.V1106L | Missense Mutation (SNP) | VAF 90/1008 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.181); catalogued as COSV52663395; called by muse, mutect2
- CSMD3 | c.5837G>A p.R1946H (on ENST00000297405 / NM_001363185.1; = p.R1842H on NM_052900.3) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779645589, COSV99828252; called by muse, mutect2, varscan2
- DNAH7 | c.9330G>A p.M3110I | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV56750966; called by muse, mutect2, varscan2
- DSCAM | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV68020328; called by muse, mutect2, varscan2
- EHMT2 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1355404952, COSV64994512; called by muse, mutect2
- EIF3E | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99622899; called by muse, mutect2, varscan2
- EPHA10 | c.2688C>G p.I896M | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs751281419, COSV57621220, COSV57626118; called by muse, mutect2, varscan2
- EPHA6 | c.2479G>A p.G827R (on ENST00000389672 / NM_001080448.3; = p.G219R on NM_173655.4) | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV67558020; called by muse, mutect2, varscan2
- ERAS | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868935025, COSV54432482; called by muse, mutect2, varscan2
- FAM199X | c.560A>C p.D187A | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55433102; called by mutect2, varscan2
- FAM83B | c.2313del p.S772Lfs*4 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | catalogued as COSV99080262; called by mutect2, pindel, varscan2
- FARSB | c.1482C>G p.Y494* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV56048013; called by muse, mutect2, varscan2
- FAT2 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55812777; called by muse, mutect2, varscan2
- FGD1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs759728785, COSV100911021, COSV64308026; called by muse, mutect2, varscan2
- FGD5 | c.2450_2451insC p.D818* | Frame Shift Ins (INS) | VAF 9/58 reads (16%) | catalogued as COSV53236851; called by mutect2, pindel, varscan2
- GDAP1 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99619419; called by muse, mutect2
- GLUD2 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1452231398, COSV60151122; called by muse, mutect2, varscan2
- HELQ | c.2759G>T p.G920V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1404241186, COSV55024045; called by muse, mutect2
- HUWE1 | c.12639G>C p.M4213I | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV53333728, COSV53351871; called by muse, mutect2, varscan2
- KIF4B | c.3359G>A p.R1120Q | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as rs373514147, COSV70531175; called by muse, mutect2, varscan2
- KRT38 | c.488A>C p.Q163P | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55845134; called by muse, varscan2
- L3MBTL4 | c.460+2T>A p.X154_splice | Splice Site (SNP) | VAF 52/167 reads (31%) | catalogued as COSV99527907; called by muse, mutect2, varscan2
- LAMB4 | c.760T>C p.Y254H | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755989607, COSV52713006; called by muse, mutect2, varscan2
- LCMT2 | c.1790A>C p.K597T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99979963; called by muse, varscan2
- LMTK3 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV54309431; called by muse, mutect2
- LRRIQ1 | c.4309G>C p.E1437Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV67825469, COSV67829538; called by muse, mutect2, varscan2
- MAGEA11 | c.843A>C p.E281D | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV100290421, COSV60758858; called by muse, mutect2
- MAP3K9 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67119764; called by muse, mutect2, varscan2
- MBNL1 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1409402696, COSV56823456; called by muse, mutect2, varscan2
- MED14 | c.1023-1G>T p.X341_splice | Splice Site (SNP) | VAF 27/320 reads (8%) | catalogued as COSV61355728; called by muse, mutect2
- MEF2A | c.599C>A p.T200N (on ENST00000557942 / NM_001319206.2; = p.T202N on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV57529654; called by muse, mutect2, varscan2
- MITF | c.356A>T p.Q119L (on ENST00000448226 / NM_006722.3; = p.Q13L on NM_000248.4) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100096635; called by muse, varscan2
- NAA40 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV58160155; called by muse, mutect2, varscan2
- NCOR1 | c.3440G>A p.G1147E | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51959791; called by muse, mutect2, varscan2
- NELL2 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV61576217; called by muse, mutect2, varscan2
- NHSL2 | c.1949C>T p.T650I (on ENST00000510661; = p.T1016I on NM_001013627.2) | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV101029938; called by muse, mutect2, varscan2
- NOS1 | c.3400A>G p.S1134G | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV57606294; called by muse, mutect2, varscan2
- NOX3 | c.777_778insG p.F260Vfs*22 | Frame Shift Ins (INS) | VAF 15/99 reads (15%) | catalogued as COSV50148554; called by mutect2, pindel, varscan2
- NR5A1 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs981580861, COSV65294564; called by muse, mutect2, varscan2
- NSRP1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 55/179 reads (31%) | catalogued as COSV99898255; called by muse, mutect2, varscan2
- OR2W1 | c.454A>C p.S152R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1308920601, COSV65851366; called by muse, mutect2, varscan2
- PAPLN | c.2737G>A p.G913S (on ENST00000554301; = p.G886S on NM_173462.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.457); catalogued as rs916781813, COSV53712747; called by muse, varscan2
- PAPSS1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs770488612, COSV54487244; called by muse, mutect2, varscan2
- PDE3B | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.994); catalogued as COSV99962180; called by muse, mutect2, varscan2
- PDE6B | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV55323643; called by muse, mutect2, varscan2
- PLEKHA1 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs771484933, COSV100935518, COSV64568938; called by muse, mutect2, varscan2
- PRPF6 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53865504; called by mutect2, varscan2
- RAI14 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 82/117 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs749996123, COSV54288874; called by muse, mutect2, varscan2
- RIC1 | c.2393A>G p.Y798C | Missense Mutation (SNP) | VAF 121/341 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs756088010, COSV52604591; called by muse, mutect2, varscan2
- RNF128 | c.-10A>G | Splice Region (SNP) | VAF 53/189 reads (28%) | catalogued as COSV60945185; called by muse, mutect2, varscan2
- RRP15 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs746555876, COSV65117216; called by muse, mutect2, varscan2
- RUFY4 | c.752A>T p.K251M | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV60245885; called by muse, mutect2, varscan2
- SCN3A | c.2607T>G p.N869K | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51800758; called by muse, mutect2, varscan2
- SDK1 | c.4416G>T p.E1472D | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as COSV67355753; called by muse, mutect2, varscan2
- SEMA5B | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52090025; called by muse, mutect2, varscan2
- SERTAD2 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as COSV57639502, COSV57641127; called by muse, mutect2, varscan2
- SLC23A3 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1224831985, COSV55405553; called by muse, mutect2, varscan2
- SLC25A3 | c.282+1G>A p.X94_splice | Splice Site (SNP) | VAF 39/147 reads (27%) | catalogued as COSV51844241; called by muse, mutect2, varscan2
- SLCO1B3 | c.1599A>C p.K533N | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV53931727; called by muse, mutect2, varscan2
- SLF2 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99488693; called by muse, mutect2, varscan2
- SRMS | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV53919727; called by muse, mutect2, varscan2
- STK31 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV63453848; called by muse, mutect2
- STS | c.1080A>T p.K360N | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54265568; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2201C>T p.T734M | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs752205982; called by muse, varscan2
- TCL1A | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1208915794, COSV68085065; called by muse, mutect2, varscan2
- TEKT2 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as COSV52880181, COSV52881023; called by muse, mutect2, varscan2
- TGM1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.683); catalogued as rs149148326; called by muse, mutect2, varscan2
- TNC | c.5605G>A p.A1869T | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100405246; called by muse, mutect2
- TNC | c.5604T>A p.F1868L | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.81); catalogued as COSV60780042; called by muse, mutect2
- TNKS1BP1 | c.4397A>T p.K1466M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV64099848; called by muse, mutect2, varscan2
- TRIM60 | c.657C>A p.N219K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs200166847; called by muse, mutect2, varscan2
- TTN | c.94091T>A p.L31364H (on ENST00000591111; = p.L23940H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/141 reads (13%) | PolyPhen possibly damaging (0.708); catalogued as COSV59873501; called by muse, mutect2, varscan2
- UBE4B | c.3572G>A p.R1191Q (on ENST00000343090 / NM_001105562.3; = p.R1062Q on NM_006048.5) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs1188510591, COSV53528294; called by muse, mutect2, varscan2
- UPRT | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975808, COSV100975810, COSV64919930; called by muse, mutect2, varscan2
- WNK3 | c.2947T>G p.S983A | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.108); catalogued as COSV63611966; called by muse, mutect2
- ZBTB7C | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV59687571; called by muse, mutect2, varscan2
- ZFP91 | c.1135C>G p.R379G | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60157005; called by muse, mutect2, varscan2
- ZNF521 | c.3574A>T p.K1192* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as COSV64121867; called by muse, mutect2
- ZNF878 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs748833064, COSV72156122; called by mutect2, varscan2
- ZNF883 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 65/150 reads (43%) | catalogued as rs201148870; called by muse, mutect2, varscan2
- CUX1 | c.3814_3815delinsT p.K1272* | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by pindel, varscan2*
- GSK3A | c.1010del p.G337Efs*11 | Frame Shift Del (DEL) | VAF 47/124 reads (38%) | called by mutect2, pindel, varscan2
- OR2A2 | c.305dup p.L102Ffs*19 | Frame Shift Ins (INS) | VAF 42/400 reads (11%) | called by mutect2, pindel, varscan2
- PGAP3 | c.370del p.R124Afs*84 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- TNKS1BP1 | c.2999del p.K1000Rfs*133 | Frame Shift Del (DEL) | VAF 37/93 reads (40%) | called by mutect2, pindel*, varscan2
- ZFHX4 | c.5018dup p.Q1674Afs*4 | Frame Shift Ins (INS) | VAF 22/168 reads (13%) | called by mutect2, pindel, varscan2
- APBA3 | c.132C>T p.P44= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs749259377, COSV57462118; called by muse, mutect2, varscan2
- CASK | c.1431C>T p.N477= | Silent (SNP) | VAF 128/278 reads (46%) | catalogued as rs375029309, COSV59361083; called by muse, mutect2, varscan2
- COL4A6 | c.4899C>T p.F1633= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as COSV100563613; called by mutect2, varscan2
- CRISP2 | c.468C>A p.P156= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV59253221; called by muse, mutect2, varscan2
- CYP3A7 | c.300T>C p.S100= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs767410266, COSV60480341; called by muse, mutect2, varscan2
- DSCAM | c.1467G>T p.S489= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV68020333, COSV68024136; called by muse, mutect2, varscan2
- EGR4 | c.1500C>G p.L500= (on ENST00000545030; = p.L397= on NM_001965.4) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV71531879; called by mutect2, varscan2
- HYDIN | c.12465C>T p.F4155= | Silent (SNP) | VAF 70/183 reads (38%) | catalogued as COSV66640724; called by muse, mutect2, varscan2
- MACC1 | c.2190C>T p.V730= | Silent (SNP) | VAF 21/203 reads (10%) | catalogued as rs373617786; called by muse, mutect2, varscan2
- MARCHF4 | c.180G>A p.A60= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV99814147; called by muse, mutect2, varscan2
- MDGA2 | c.1596G>A p.L532= (on ENST00000399232 / NM_001113498.2; = p.L234= on NM_182830.4) | Silent (SNP) | VAF 21/256 reads (8%) | catalogued as rs1485890179, COSV62078377; called by muse, mutect2
- MKI67 | c.810C>T p.Y270= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs201621002, COSV64072423; called by muse, mutect2, varscan2
- NMBR | c.378C>T p.S126= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV57800361; called by muse, mutect2, varscan2
- OR10K2 | c.417G>C p.G139= | Silent (SNP) | VAF 61/241 reads (25%) | catalogued as COSV59220324; called by muse, mutect2, varscan2
- OR4K15 | c.729T>C p.T243= (on ENST00000305051; = p.T219= on NM_001005486.1) | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs1231687869, COSV100521000; called by muse, mutect2, varscan2
- PATJ | c.2715A>G p.E905= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100333447; called by muse, mutect2, varscan2
- PCDHGA12 | c.237G>A p.P79= | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as rs1256552269, COSV99338779; called by muse, mutect2, varscan2
- PCNX3 | c.3456C>T p.A1152= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs764500917, COSV63134499; called by muse, mutect2, varscan2
- PGF | c.45C>T p.A15= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as rs751945485, COSV53124461; called by muse, mutect2, varscan2
- PLA2G2A | c.429T>A p.R143= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV100908611; called by muse, mutect2, varscan2
- PLXNA3 | c.4026C>T p.F1342= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs782050805, COSV63753093; called by muse, mutect2, varscan2
- PPDPF | c.39C>T p.T13= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100925637; called by muse, mutect2
- RBAK-RBAKDN | c.612G>A p.G204= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as rs1362093021, COSV101208248; called by muse, mutect2, varscan2
- SIGLEC1 | c.4788G>C p.L1596= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV52458380; called by muse, mutect2, varscan2
- SMPX | c.12G>A p.S4= | Silent (SNP) | VAF 73/342 reads (21%) | catalogued as rs375612194, COSV65277051; called by muse, mutect2, varscan2
- SOD1 | c.339C>T p.I113= | Silent (SNP) | VAF 66/199 reads (33%) | catalogued as rs1299542356, CM983783, COSV54255447; called by muse, mutect2, varscan2
- STS | c.1455C>T p.F485= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs931206122, COSV54267716; called by muse, mutect2, varscan2
- TGM6 | c.231G>A p.S77= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs139331856; called by muse, mutect2, varscan2
- ZFHX3 | c.4497G>A p.L1499= | Silent (SNP) | VAF 44/374 reads (12%) | catalogued as COSV51707243; called by muse, mutect2, varscan2
- ZSCAN4 | c.861T>C p.L287= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- BICD2 | c.2469+37G>A | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as rs779724776, COSV100794026; ClinVar: uncertain significance; called by mutect2, varscan2
- HLA-L | n.849G>T | RNA (SNP) | VAF 61/240 reads (25%) | called by muse, mutect2, varscan2
